Somatic mutation profile of tumor specimen ALCH-B3ZP-TTP1-A (aliquot ALCH-B3ZP-TTP1-A-2-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,135 days).
Specimen ALCH-B3ZP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2553a0a5-cf11-4c3e-98b9-8fc7084e56b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZP-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZP-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/564e57f7-b48b-4497-be5d-acbbd405f3fd

The open-access MAF lists 54 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 5, 5'UTR 2, Nonsense Mutation 2, 3'UTR 2, RNA 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 19/203 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD30A | c.1859C>A p.T620N (on ENST00000611781; = p.T564N on NM_052997.2) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs946102099; called by muse, mutect2, varscan2
- BOD1L1 | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1211536251; called by muse, mutect2
- CACNA2D3 | c.3161C>G p.S1054C | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55535830; called by muse, mutect2, varscan2
- CD4 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV50594058, COSV50594373; called by muse, mutect2, varscan2
- COL27A1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs747384879; called by muse, mutect2, varscan2
- DNAH2 | c.2376G>T p.L792F | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV101209483; called by muse, mutect2
- FAM136A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.422); catalogued as rs747156050; called by muse, mutect2, varscan2
- HEPACAM | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100005368; called by muse, mutect2
- MARCHF5 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs1458725282, COSV62768832; called by muse, mutect2, varscan2
- NUF2 | c.234A>T p.L78F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1182521638; called by muse, mutect2, varscan2
- PTH2R | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs145269926; called by muse, mutect2, varscan2
- PTPRT | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV61982755; called by muse, mutect2, varscan2
- SPINK5 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 35/200 reads (18%) | catalogued as rs776293648, COSV56251987; called by muse, mutect2, varscan2
- ZNF646 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56211367; called by muse, mutect2, varscan2
- ADCY1 | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CDK13 | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLIC4 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ERI3 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HROB | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- IDH1 | c.173_178del p.K58_A60delinsT | In Frame Del (DEL) | VAF 22/130 reads (17%) | called by mutect2, pindel, varscan2
- NPR3 | c.1555G>A p.E519K (on ENST00000265074 / NM_001364458.2; = p.E518K on NM_000908.4) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2
- NRAP | c.1871G>A p.S624N (on ENST00000359988 / NM_001322945.2; = p.S589N on NM_006175.4) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR5W2 | c.491T>C p.F164S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- OR8J3 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PCNX3 | c.5468A>G p.K1823R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PDCL3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SIN3B | c.227+1G>A p.X76_splice | Splice Site (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TSC22D1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by mutect2, varscan2
- UNKL | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- CDC42SE2 | c.243G>T p.T81= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV64759090; called by muse, mutect2, varscan2
- EID3 | c.141C>A p.L47= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- FAAH | c.942C>T p.F314= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV54543556; called by muse, mutect2, varscan2
- NLRP12 | c.1452C>T p.H484= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs769866276, COSV60755872; called by muse, mutect2, varscan2
- NOC4L | c.1401C>T p.I467= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs994290009; called by muse, varscan2
- OR6K6 | c.624T>C p.D208= (on ENST00000368144; = p.D184= on NM_001005184.1) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV63743834; called by muse, mutect2
- PHLPP1 | c.432G>A p.S144= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- RUSC1 | c.1857T>C p.D619= (on ENST00000368352 / NM_001105203.2; = p.D150= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 23/233 reads (10%) | catalogued as rs771543531; called by muse, mutect2, varscan2
- SYT16 | c.1737C>T p.F579= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as COSV70855391; called by muse, mutect2
- TBX3 | c.456G>A p.L152= | Silent (SNP) | VAF 12/245 reads (5%) | called by muse, mutect2
- TMEM63B | c.2481G>A p.E827= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- TRIP12 | c.5919A>T p.I1973= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- ZC3H12C | c.2043C>T p.H681= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs376308496; called by muse, mutect2, varscan2
- ASPH | c.976+11660C>T | Intron (SNP) | VAF 20/95 reads (21%) | catalogued as rs567108586; called by muse, mutect2, varscan2
- BST1 | c.189-558A>T | Intron (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- CLCN1 | c.-10G>A | 5'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- COILP1 | n.201C>T | RNA (SNP) | VAF 3/19 reads (16%) | catalogued as rs994281215; called by muse, varscan2
- DHCR24 | c.-2C>T | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- MLXIP | c.2509-96G>A | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs1360695337; called by muse, mutect2
- OSCAR | c.*385C>T | 3'UTR (SNP) | VAF 3/25 reads (12%) | catalogued as rs1442263644; called by muse, mutect2
- SERPINB13 | c.473-176_473-175insT | Intron (INS) | VAF 14/112 reads (13%) | called by mutect2, pindel*, varscan2
- SLC11A2 | c.*306A>G | 3'UTR (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- SNORD115-43 | n.69T>G | RNA (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26366A>G | Intron (SNP) | VAF 10/62 reads (16%) | catalogued as rs781228658; called by muse, mutect2, varscan2
